Gene-level copy-number profile of specimen HCM-CSHL-0191-C25-85A from HCMI case HCM-CSHL-0191-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 75.5 years (27,561 days).
Specimen HCM-CSHL-0191-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d8b71eac-1632-4eac-9ce6-ceef5af43d00.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0191-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/cd1d5e84-c774-498a-a401-0793e98c6d19

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 743; copy number 2: 7,996; copy number 3: 9,672; copy number 4: 22,806; copy number 5: 13,683; copy number 6: 3,915; copy number 7: 57; copy number 8: 21; copy number 9: 2; copy number 10: 4; copy number 14: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:246,682,108–246,691,821, 2 genes, copy number 9: AL591848.2, AL591848.1.
- chr16:32,356,981–32,380,049, 2 genes, copy number 14: AC133548.1, ACTR3BP3.
- chr17:22,606,388–22,706,703, 4 genes, copy number 10: AC131055.1, AC131274.3, AC131274.1, AC131274.2.

Autosomal genes at a single copy (total copy number 1): 231. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
